Somatic mutation profile of tumor specimen TCGA-34-5928-01A (aliquot TCGA-34-5928-01A-11D-1817-08) from TCGA case TCGA-34-5928, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 83.0 years (30,334 days).
Specimen TCGA-34-5928-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad91b604-0990-4114-974c-a9975d6811e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-5928-10A (Blood Derived Normal), aliquot TCGA-34-5928-10A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64b973a2-c5f4-486f-93cf-0bda12349636

The open-access MAF lists 373 somatic variants for this specimen: 276 protein-altering or splice-affecting, 92 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 248, Silent 92, Nonsense Mutation 22, Intron 4, Splice Site 3, Translation Start Site 1, Nonstop Mutation 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2C | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 88/337 reads (26%) | hotspot (GDC flag); catalogued as rs1283285486, COSV51288537; called by muse, mutect2, varscan2
- ABCA1 | c.3938G>T p.G1313V | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV66067763; called by muse, mutect2, varscan2
- ABCA1 | c.3937G>T p.G1313C | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV66067765; called by muse, mutect2, varscan2
- ABCA13 | c.8640C>G p.F2880L | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as COSV71290640; called by muse, mutect2, varscan2
- ABCA4 | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64674778, COSV64676704; called by muse, mutect2
- ABCC5 | c.3770G>C p.R1257T | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV55592532; called by muse, mutect2
- ABRA | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 5/132 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV61732793; called by muse, mutect2
- ACD | c.294G>A p.W98* (on ENST00000620338; = p.W12* on NM_022914.3) | Nonsense Mutation (SNP) | VAF 21/113 reads (19%) | catalogued as rs1244950221, COSV54668624; called by muse, mutect2, varscan2
- ACTA1 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 16/173 reads (9%) | catalogued as COSV64203607; called by muse, mutect2
- ADAM18 | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55850106; called by muse, mutect2, varscan2
- ADAM23 | c.739C>A p.H247N | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV52219770; called by muse, mutect2
- ADCY1 | c.2318C>T p.T773I | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as COSV52037152; called by muse, mutect2, varscan2
- ADCY10 | c.1367C>G p.S456C | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.72); catalogued as COSV63241674, COSV63242035; called by muse, mutect2, varscan2
- ADCY3 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV53169242; called by muse, mutect2, varscan2
- ADGRF1 | c.1092C>A p.F364L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV51946301; called by muse, mutect2, varscan2
- ADGRF5 | c.2574C>G p.I858M | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV51936255; called by muse, mutect2
- ADGRL3 | c.853G>T p.A285S (on ENST00000506720 / NM_001322402.2; = p.A217S on NM_015236.6) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV72269345; called by muse, mutect2, varscan2
- ADNP2 | c.2503G>T p.G835W | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51540152; called by muse, mutect2, varscan2
- AKNAD1 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 32/221 reads (14%) | catalogued as rs1487882388, COSV62199967; called by muse, mutect2, varscan2
- ALDH2 | c.1540C>G p.Q514E | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV55668577; called by muse, mutect2, varscan2
- ALMS1 | c.12130C>G p.H4044D | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52513439; called by muse, mutect2, varscan2
- ALS2 | c.1984C>G p.L662V | Missense Mutation (SNP) | VAF 46/304 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV51888802; called by muse, mutect2, varscan2
- AMACR | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs749253247, COSV56872977; called by muse, mutect2
- ANGPT1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.101); catalogued as COSV52445707; called by muse, mutect2, varscan2
- ANKRD11 | c.7432C>A p.L2478M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56363984; called by muse, mutect2, varscan2
- ANKRD30A | c.1762C>A p.Q588K (on ENST00000611781; = p.Q532K on NM_052997.2) | Missense Mutation (SNP) | VAF 79/552 reads (14%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.678); catalogued as COSV64608458, COSV64612335, COSV64619155; called by muse, mutect2, varscan2
- ANKRD30A | c.2476C>A p.Q826K (on ENST00000611781; = p.Q770K on NM_052997.2) | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.79); PolyPhen benign (0.184); catalogued as COSV64619164; called by mutect2, varscan2
- ANO5 | c.1999C>G p.L667V | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as COSV61086995; called by muse, mutect2, varscan2
- APBA2 | c.2033G>C p.G678A | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV68790698; called by muse, mutect2, varscan2
- ARAP1 | c.2663G>C p.G888A (on ENST00000393609 / NM_001040118.2; = p.G643A on NM_015242.4) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV61992144, COSV61995718; called by muse, mutect2, varscan2
- ARG1 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51581293; called by muse, mutect2, varscan2
- ARHGAP35 | c.695C>A p.S232Y | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.65); catalogued as COSV68332812; called by muse, mutect2, varscan2
- ASH1L | c.6236C>G p.S2079* (on ENST00000368346 / NM_001366177.2; = p.S2074* on NM_018489.3) | Nonsense Mutation (SNP) | VAF 5/126 reads (4%) | catalogued as COSV100853195, COSV64209924; called by muse, mutect2
- ATG2A | c.3536A>G p.D1179G | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1177575639, COSV65967355; called by muse, mutect2, varscan2
- ATP13A5 | c.1076C>G p.S359C | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.852); catalogued as COSV100664726, COSV60871269; called by muse, mutect2
- ATP5F1C | c.34G>C p.A12P | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.328); catalogued as COSV59622104; called by muse, mutect2, varscan2
- BCORL1 | c.3551A>T p.K1184M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV54399503; called by muse, mutect2, varscan2
- BICRA | c.3598G>T p.E1200* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV67603865, COSV67605300; called by muse, mutect2, varscan2
- BIRC3 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs373651361, COSV54817821, COSV54818027; called by muse, mutect2, varscan2
- BIRC6 | c.10090G>T p.A3364S | Missense Mutation (SNP) | VAF 81/337 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.146); catalogued as rs1325788526, COSV70201863; called by muse, mutect2, varscan2
- BPIFB2 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV50066426; called by muse, mutect2, varscan2
- BTBD9 | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58429830; called by muse, mutect2, varscan2
- BUB1B | c.1856C>G p.S619C | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55014008; called by muse, varscan2
- C8orf34 | c.1095G>A p.M365I | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.946); catalogued as COSV61385037; called by muse, mutect2, varscan2
- CADM1 | c.598A>T p.T200S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV59014707; called by muse, mutect2, varscan2
- CADPS2 | c.3181G>C p.E1061Q | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.282); catalogued as COSV57370860; called by muse, mutect2
- CADPS2 | c.2533G>C p.E845Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57370883; called by muse, mutect2, varscan2
- CAPZA1 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 57/199 reads (29%) | catalogued as COSV54145980; called by muse, mutect2, varscan2
- CCDC174 | c.1003C>G p.P335A | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100358468, COSV57981348; called by muse, mutect2, varscan2
- CCDC80 | c.1900G>C p.E634Q | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.406); catalogued as COSV52817972; called by muse, mutect2
- CD109 | c.4166G>A p.R1389K | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.374); catalogued as COSV54652135; called by muse, mutect2, varscan2
- CDC73 | c.729G>T p.K243N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV66468053; called by muse, mutect2
- CENPA | c.150G>C p.E50D | Missense Mutation (SNP) | VAF 4/91 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1468947606, COSV51982948; called by muse, mutect2
- CEP112 | c.755T>C p.I252T | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as COSV67140194, COSV67141657; called by muse, mutect2, varscan2
- CFAP47 | c.1312A>C p.N438H | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52887303; called by muse, mutect2, varscan2
- CFAP74 | c.1283T>A p.L428* | Nonsense Mutation (SNP) | VAF 24/76 reads (32%) | catalogued as COSV54569748; called by muse, mutect2, varscan2
- CHD4 | c.3736G>C p.D1246H (on ENST00000357008 / NM_001363606.2; = p.D1259H on NM_001273.5) | Missense Mutation (SNP) | VAF 13/225 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58904456; called by muse, mutect2
- CHST8 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs368093515; called by muse, mutect2, varscan2
- CIDEC | c.691C>G p.P231A | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.049); catalogued as rs766183487, COSV61062107; called by muse, mutect2, varscan2
- CNTNAP4 | c.3424G>C p.V1142L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as COSV56687960; called by muse, mutect2, varscan2
- COL5A2 | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV66411172, COSV66412055; called by muse, mutect2
- CPNE5 | c.1115A>T p.H372L | Missense Mutation (SNP) | VAF 69/112 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV55197759; called by muse, mutect2, varscan2
- CRISP3 | c.623G>T p.W208L (on ENST00000371159 / NM_001368123.1; = p.W190L on NM_006061.4) | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1369397591, COSV53821444, COSV99538838; called by muse, mutect2, varscan2
- CRYGD | c.375C>A p.N125K | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.756); catalogued as rs529629277, COSV52205562, COSV52205620; called by muse, mutect2, varscan2
- CTNNA2 | c.2074C>G p.Q692E | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100559527, COSV58160643; called by muse, mutect2, varscan2
- CUL3 | c.159T>G p.S53R | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52366473; called by muse, mutect2, varscan2
- CXCR4 | c.72G>A p.M24I | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV54011991, COSV54013717; called by muse, mutect2, varscan2
- CYP17A1 | c.1476G>C p.K492N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.444); catalogued as COSV64004997; called by muse, mutect2, varscan2
- DAZL | c.621+1G>A p.X207_splice | Splice Site (SNP) | VAF 15/35 reads (43%) | catalogued as COSV51712967, COSV51713393; called by muse, mutect2, varscan2
- DCX | c.499A>T p.S167C | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV100576434, COSV57571463; called by muse, mutect2, varscan2
- DEFB125 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.264); catalogued as COSV66703394; called by muse, mutect2
- DENND4C | c.5753A>G p.N1918S (on ENST00000434457 / NM_001330640.2; = p.N1869S on NM_017925.7) | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs370152905; called by muse, mutect2, varscan2
- DISP1 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 30/279 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs369580331; called by muse, mutect2, varscan2
- DMP1 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV56820739, COSV99218791; called by muse, mutect2, varscan2
- DNAH8 | c.10782G>C p.R3594S | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV59458906; called by muse, mutect2, varscan2
- DRD3 | c.1188G>C p.K396N | Missense Mutation (SNP) | VAF 187/610 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55678607; called by muse, mutect2, varscan2
- DUSP5 | c.1018G>T p.G340C | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV63646467; called by muse, mutect2, varscan2
- EFHB | c.2473G>T p.D825Y | Missense Mutation (SNP) | VAF 65/190 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); catalogued as COSV55549740; called by muse, mutect2, varscan2
- EGLN3 | c.173A>T p.D58V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV51655356; called by muse, mutect2, varscan2
- EGR2 | c.1169G>C p.R390P | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54347453; called by muse, mutect2, varscan2
- EHD4 | c.1005C>G p.I335M | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV55005603; called by muse, mutect2
- ELAPOR2 | c.3068C>T p.T1023I (on ENST00000450689 / NM_001142749.3; = p.T856I on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV51888329; called by muse, mutect2, varscan2
- ENAH | c.1711A>T p.T571S (on ENST00000366844 / NM_001008493.3; = p.T550S on NM_018212.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.349); catalogued as COSV52869645; called by muse, mutect2
- EPPK1 | c.4004C>T p.S1335F | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs1554660271, COSV73261644; called by muse, mutect2, varscan2
- FAM126B | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 10/83 reads (12%) | catalogued as COSV53773498; called by muse, mutect2, varscan2
- FAM180A | c.419C>A p.S140Y | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV58528787; called by muse, mutect2, varscan2
- FAT1 | c.5980G>A p.E1994K | Missense Mutation (SNP) | VAF 61/489 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs781014362, COSV71673540, COSV71674847; called by muse, mutect2, varscan2
- FBXO3 | c.1312G>C p.D438H | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.99); catalogued as COSV55767006; called by muse, mutect2, varscan2
- FCRL2 | c.819T>A p.Y273* | Nonsense Mutation (SNP) | VAF 42/244 reads (17%) | catalogued as COSV100829991, COSV63834073; called by muse, mutect2, varscan2
- FLNA | c.3001C>G p.Q1001E | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.262); catalogued as COSV61046251; called by muse, mutect2, varscan2
- FOXN1 | c.1059C>G p.I353M | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs762513012, COSV56882628; called by muse, mutect2, varscan2
- FRAS1 | c.7301C>T p.P2434L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs566641641, COSV53593919; called by muse, mutect2, varscan2
- GABRA1 | c.281G>T p.R94L | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV50099709, COSV50102525; called by muse, mutect2, varscan2
- GABRG1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV54950130, COSV99778230; called by muse, mutect2, varscan2
- GARNL3 | c.1654C>G p.R552G | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.681); catalogued as COSV104407667, COSV59227905; called by muse, mutect2, varscan2
- GART | c.1540C>T p.Q514* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as rs778891157, COSV63113987; called by muse, mutect2, varscan2
- GLRA4 | c.762G>T p.Q254H | Missense Mutation (SNP) | VAF 77/189 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV65456390; called by muse, mutect2, varscan2
- GLUD2 | c.198C>G p.F66L | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as rs1329000964, COSV60152277; called by muse, mutect2, varscan2
- GPATCH1 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV50118456; called by muse, mutect2
- GRIA3 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV52068277; called by muse, mutect2, varscan2
- GSG1L | c.632C>G p.P211R (on ENST00000447459 / NM_001109763.2; = p.P56R on NM_144675.2) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101093909, COSV66579903; called by muse, mutect2, varscan2
- HAUS5 | c.1816G>C p.E606Q | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.12); catalogued as COSV52548454; called by muse, mutect2
- HCN1 | c.1058T>C p.M353T | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV57519804; called by muse, mutect2, varscan2
- HMGCS1 | c.21G>C p.L7F | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.282); catalogued as COSV57290634; called by muse, mutect2
- HOXC10 | c.168G>T p.R56S | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV57726608; called by muse, mutect2, varscan2
- HRH4 | c.705G>T p.R235S | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV56928607; called by muse, mutect2, varscan2
- HSPA5 | c.1140T>A p.N380K | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); catalogued as COSV52336531; called by muse, mutect2
- IFI44 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.598); catalogued as COSV66075076; called by muse, mutect2, varscan2
- IFNA8 | c.359A>G p.E120G | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs376876265; called by muse, mutect2
- IL1RAPL1 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs756376051, COSV56274784; called by muse, mutect2, varscan2
- INPP5J | c.1934A>G p.K645R (on ENST00000331075 / NM_001284285.2; = p.K277R on NM_001002837.2) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.194); catalogued as COSV58513761; called by muse, mutect2
- IQGAP1 | c.1705G>T p.E569* | Nonsense Mutation (SNP) | VAF 12/81 reads (15%) | catalogued as COSV51587474; called by muse, mutect2, varscan2
- ISG15 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.588); catalogued as rs748078443, COSV65106536; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGA8 | c.1118A>T p.D373V | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.818); catalogued as COSV65231169; called by muse, mutect2, varscan2
- ITSN2 | c.2684G>A p.G895E | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764409422, COSV61949682; called by muse, mutect2, varscan2
- KDR | c.2309G>T p.G770V | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55758364; called by muse, mutect2, varscan2
- KDR | c.2308G>T p.G770C | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55768754; called by muse, mutect2, varscan2
- KIAA0100 | c.883C>T p.Q295* | Nonsense Mutation (SNP) | VAF 55/118 reads (47%) | catalogued as COSV66494306; called by muse, mutect2, varscan2
- KIAA1841 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV54376160; called by muse, mutect2, varscan2
- KIF21B | c.3679C>T p.Q1227* | Nonsense Mutation (SNP) | VAF 16/95 reads (17%) | catalogued as COSV59760495; called by muse, mutect2, varscan2
- KLHL1 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64775416; called by muse, mutect2, varscan2
- KMT2D | c.10678G>A p.D3560N | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56456697; called by muse, mutect2, varscan2
- KRBA1 | c.1487G>A p.G496E | Missense Mutation (SNP) | VAF 80/288 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55442410; called by muse, mutect2, varscan2
- LACTB2 | c.125G>C p.R42T | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52568341, COSV52568614; called by muse, mutect2, varscan2
- LARP6 | c.1146G>A p.W382* | Nonsense Mutation (SNP) | VAF 7/66 reads (11%) | catalogued as COSV54580764; called by muse, mutect2, varscan2
- LGR4 | c.759-1G>C p.X253_splice | Splice Site (SNP) | VAF 8/75 reads (11%) | catalogued as COSV64864943; called by muse, mutect2, varscan2
- LHX8 | c.478G>C p.A160P | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53957791; called by muse, mutect2, varscan2
- LONRF3 | c.1078C>T p.H360Y (on ENST00000371628 / NM_001031855.3; = p.H319Y on NM_024778.5) | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.186); catalogued as COSV59154079; called by muse, mutect2, varscan2
- LRBA | c.6587G>A p.R2196H | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs760622773, COSV63958248; called by muse, mutect2, varscan2
- LRP1B | c.13015G>T p.D4339Y | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs1157366415, COSV67241472; called by muse, mutect2, varscan2
- LRP1B | c.8248G>C p.D2750H | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67241479; called by muse, mutect2, varscan2
- MACF1 | c.15958G>C p.E5320Q (on ENST00000372915; = p.E3253Q on NM_012090.5) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as COSV57129009; called by muse, mutect2, varscan2
- MADD | c.956A>G p.E319G | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60625925; called by muse, mutect2, varscan2
- MAGEA11 | c.816A>T p.Q272H | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as COSV100290414; called by muse, mutect2, varscan2
- MAL2 | c.374C>G p.S125C | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as rs749996607, COSV52661721; called by muse, mutect2
- MAP2 | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 51/314 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52296848; called by muse, mutect2, varscan2
- MAPKAP1 | c.91C>G p.L31V | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV56370125; called by muse, mutect2
- MCF2L2 | c.2745G>T p.R915S | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as COSV61056511; called by muse, mutect2, varscan2
- MGA | c.3208C>A p.H1070N | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54953019, COSV54957183; called by muse, mutect2, varscan2
- MOV10L1 | c.2293C>T p.P765S | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53174287; called by muse, mutect2, varscan2
- MPHOSPH6 | c.115A>G p.I39V | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.388); catalogued as COSV50737094; called by muse, mutect2, varscan2
- MPP3 | c.1708G>C p.E570Q | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.299); catalogued as COSV68198399; called by muse, mutect2, varscan2
- MROH2B | c.3972C>G p.I1324M | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV68182795; called by muse, mutect2
- MS4A6A | c.339G>T p.L113F | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60620167; called by muse, mutect2, varscan2
- MTX1 | c.654G>C p.K218N | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); catalogued as COSV57427157; called by muse, mutect2
- MUC2 | c.3544G>C p.V1182L | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs1277455961; called by muse, mutect2, varscan2
- MXRA5 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as COSV54240168, COSV54242088; called by muse, mutect2, varscan2
- MYEOV | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as COSV58294681, COSV58294738; called by muse, mutect2
- NAALADL2 | c.2095G>C p.E699Q | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV71985445; called by muse, mutect2, varscan2
- NAPA | c.71C>G p.S24W | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54550685; called by muse, mutect2, varscan2
- NAV3 | c.77T>A p.I26K | Missense Mutation (SNP) | VAF 99/231 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV57090907; called by muse, mutect2, varscan2
- NAV3 | c.6776A>C p.D2259A (on ENST00000397909 / NM_001024383.2; = p.D2237A on NM_014903.6) | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57090917; called by muse, mutect2, varscan2
- NCKAP1L | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 78/205 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.257); catalogued as rs1201643257, COSV53208668; called by muse, varscan2
- NEB | c.2536A>T p.K846* | Nonsense Mutation (SNP) | VAF 8/171 reads (5%) | catalogued as COSV51429875; called by muse, mutect2
- NF1 | c.1696C>G p.P566A | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.61); catalogued as COSV62208635; called by muse, mutect2
- NKAIN2 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 10/95 reads (11%) | catalogued as COSV63716749; called by muse, mutect2
- NOC3L | c.1979A>G p.D660G | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1361142161, COSV64930076; called by muse, mutect2, varscan2
- NOTCH2 | c.1362G>C p.E454D | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV56692259; called by muse, mutect2, varscan2
- NR3C1 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs766706619, COSV51544343; called by muse, mutect2, varscan2
- NRBP1 | c.516G>C p.M172I | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV51994822; called by muse, mutect2
- NYX | c.26T>A p.L9Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as COSV61181161; called by muse, mutect2, varscan2
- OAS1 | c.391G>C p.A131P | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.934); catalogued as COSV52536886; called by muse, mutect2, varscan2
- OLFM3 | c.977G>A p.R326Q (on ENST00000338858 / NM_001288821.1; = p.R306Q on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1278883199, COSV58800476; called by muse, mutect2
- ONECUT1 | c.736G>T p.G246C | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs764411723, COSV59949632; called by muse, mutect2, varscan2
- OPA1 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.214); catalogued as rs149756039; called by muse, mutect2, varscan2
- OR13C4 | c.14A>T p.N5I | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52927394; called by muse, mutect2, varscan2
- OR2T6 | c.79T>C p.F27L | Missense Mutation (SNP) | VAF 90/186 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63216616; called by muse, mutect2
- OR4D11 | c.427G>C p.A143P | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.756); catalogued as COSV57586178; called by muse, mutect2, varscan2
- OR4Q3 | c.761C>G p.T254R | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV59179192; called by muse, mutect2, varscan2
- OR4X2 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56583925; called by muse, mutect2, varscan2
- OR5I1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1239931522, COSV56887200; called by muse, mutect2
- OR8B3 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.162); catalogued as COSV63541888; called by muse, mutect2, varscan2
- OR8G5 | c.695A>C p.E232A | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.052); catalogued as COSV100422276, COSV58379636; called by muse, varscan2
- OTP | c.115G>T p.G39W | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV60569242; called by muse, mutect2
- OXCT1 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs778805908, COSV52172958; called by muse, mutect2, varscan2
- PAQR5 | c.242C>A p.S81Y | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.767); catalogued as COSV61818341; called by muse, mutect2
- PCDH10 | c.2669A>T p.D890V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.617); catalogued as COSV52097561; called by muse, mutect2, varscan2
- PCDHA3 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.082); catalogued as COSV63538578; called by muse, mutect2, varscan2
- PCDHA5 | c.641C>G p.T214S | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.242); catalogued as COSV65353759, COSV65356756; called by muse, mutect2, varscan2
- PCDHB9 | c.2254G>C p.E752Q | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV53375579, COSV53380716; called by muse, mutect2
- PCDHGA7 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.967); catalogued as COSV53975828; called by muse, mutect2, varscan2
- PCDHGC5 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1156924462, COSV52756989; called by muse, mutect2, varscan2
- PCF11 | c.3094G>C p.E1032Q | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as COSV53533632; called by muse, mutect2, varscan2
- PCM1 | c.2327C>T p.S776L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.563); catalogued as COSV61517530; called by muse, mutect2
- PDE1B | c.587G>T p.R196L | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV54493968; called by muse, mutect2, varscan2
- PDPK1 | c.1477G>C p.V493L | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as COSV51913502; called by muse, mutect2
- PDYN | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs745539811, COSV54100725; called by muse, mutect2, varscan2
- PFKP | c.2109G>C p.E703D | Missense Mutation (SNP) | VAF 13/328 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV56533961; called by muse, mutect2
- PIK3R6 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.493); catalogued as COSV61004012; called by muse, mutect2, varscan2
- PIP5K1C | c.1932G>C p.E644D | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV58953702; called by muse, mutect2
- PLAU | c.1002G>C p.M334I | Missense Mutation (SNP) | VAF 81/156 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.665); catalogued as COSV65641651; called by muse, mutect2, varscan2
- PLCB2 | c.237G>C p.Q79H | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV53035121; called by muse, mutect2
- PLEKHA5 | c.2179T>A p.Y727N | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.379); catalogued as COSV54704452; called by muse, mutect2, varscan2
- PLXNB1 | c.3329G>C p.G1110A | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1460333746, COSV56491405; called by muse, mutect2, varscan2
- PLXNC1 | c.4016G>A p.R1339Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV51577834; called by muse, mutect2, varscan2
- PNLIPRP3 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 124/212 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100982483, COSV65048755; called by muse, mutect2, varscan2
- POU3F3 | c.1053C>A p.Y351* | Nonsense Mutation (SNP) | VAF 42/107 reads (39%) | catalogued as COSV63721979, COSV63722477; called by muse, mutect2, varscan2
- PPFIA4 | c.2200C>A p.P734T (on ENST00000447715; = p.P735T on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV55317307; called by muse, mutect2
- PPIP5K2 | c.391A>T p.I131L | Missense Mutation (SNP) | VAF 135/283 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV58606941; called by muse, mutect2, varscan2
- PPM1B | c.382G>C p.D128H | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56767664; called by muse, mutect2
- PREX2 | c.4595G>A p.G1532D | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55780558; called by muse, mutect2, varscan2
- PRKDC | c.3267C>G p.F1089L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.788); catalogued as COSV58056512; called by muse, mutect2, varscan2
- PTCH2 | c.2540G>C p.R847T | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV64711796; called by muse, mutect2, varscan2
- PTCH2 | c.2023C>T p.Q675* | Nonsense Mutation (SNP) | VAF 15/105 reads (14%) | catalogued as COSV64711804; called by muse, mutect2, varscan2
- PTPRT | c.4072C>T p.R1358* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as COSV61966484, COSV62022626; called by muse, mutect2, varscan2
- RAB17 | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV52816262; called by muse, mutect2
- RANBP2 | c.3376C>T p.R1126W | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs370285906; ClinVar: likely benign; called by muse, mutect2, varscan2
- RBM38 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as rs778455042, COSV61134515; called by muse, mutect2, varscan2
- RBM6 | c.125G>C p.R42T | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56484650; called by muse, mutect2, varscan2
- REG1B | c.499T>A p.*167Kext*16 | Nonstop Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as rs909429740, COSV59306416; called by muse, mutect2, varscan2
- RYR3 | c.13263C>A p.F4421L (on ENST00000389232; = p.F4422L on NM_001036.6) | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66797203; called by muse, mutect2, varscan2
- SCAMP1 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 113/266 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.437); catalogued as COSV57241075; called by muse, mutect2, varscan2
- SERPINB5 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.238); catalogued as COSV66975703; called by muse, mutect2, varscan2
- SERPINE2 | c.407G>A p.C136Y | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV51458442; called by muse, mutect2, varscan2
- SERPINI2 | c.760G>C p.A254P | Missense Mutation (SNP) | VAF 41/293 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.659); catalogued as COSV52987071; called by muse, mutect2, varscan2
- SEZ6L2 | c.1750G>A p.D584N (on ENST00000308713 / NM_001114099.3; = p.D514N on NM_012410.4) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58098720; called by muse, mutect2, varscan2
- SI | c.356T>C p.M119T | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV52285968; called by muse, mutect2, varscan2
- SKAP1 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 126/482 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.1); catalogued as COSV61148255; called by muse, mutect2, varscan2
- SLC25A13 | c.1682G>C p.G561A | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55709456; called by muse, mutect2, varscan2
- SLC30A3 | c.222G>T p.R74S | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV51986359; called by muse, mutect2, varscan2
- SLC39A4 | c.322G>A p.E108K (on ENST00000301305 / NM_001374839.1; = p.E83K on NM_017767.3) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.03); catalogued as rs144726882; called by muse, mutect2
- SLC6A3 | c.1844G>C p.R615P | Missense Mutation (SNP) | VAF 48/257 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.669); catalogued as COSV54363137, COSV54365852; called by muse, mutect2, varscan2
- SLCO4C1 | c.2167G>C p.E723Q | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.478); catalogued as COSV60513866, COSV60517155; called by muse, mutect2
- SMPD1 | c.789G>C p.L263F | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.076); catalogued as COSV54968911; called by muse, mutect2
- SMTN | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60779917; called by muse, mutect2
- SOX30 | c.998G>C p.R333T | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV53938133; called by muse, mutect2
- SPATA2 | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV56867230, COSV56868322; called by muse, mutect2, varscan2
- SPEF2 | c.2899G>T p.A967S | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773002918, COSV61548840, COSV61549825; called by muse, mutect2, varscan2
- SPHKAP | c.644T>A p.L215H | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60884182; called by muse, mutect2, varscan2
- SPSB1 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV60163770; called by muse, mutect2, varscan2
- SPTBN4 | c.5392G>A p.G1798S | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58953164; called by muse, mutect2, varscan2
- ST3GAL5 | c.172A>T p.R58* | Nonsense Mutation (SNP) | VAF 35/100 reads (35%) | catalogued as rs1161788315, COSV60386231; called by muse, mutect2, varscan2
- STOX2 | c.1558G>C p.D520H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV57853655; called by muse, mutect2, varscan2
- SULT1C2 | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52265595; called by muse, mutect2, varscan2
- TAS2R60 | c.857A>G p.Y286C | Missense Mutation (SNP) | VAF 125/319 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1335269888, COSV60331254; called by muse, mutect2, varscan2
- TBC1D8B | c.1228G>C p.E410Q | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV52180379; called by muse, mutect2, varscan2
- TFAP2B | c.113C>A p.S38* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as COSV53828943; called by muse, mutect2
- TGFBRAP1 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1020232911, COSV51513611; called by muse, mutect2
- TGOLN2 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 99/533 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV56406581; called by muse, mutect2, varscan2
- TKFC | c.837C>G p.I279M | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV101204184, COSV67523776; called by muse, mutect2
- TKTL2 | c.1345G>T p.V449F | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54919747; called by muse, mutect2, varscan2
- TLR2 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV52604947; called by muse, mutect2, varscan2
- TMEM267 | c.209G>C p.G70A | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV67992897; called by muse, mutect2, varscan2
- TOPORS | c.1334C>T p.S445L | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV62117356; called by muse, mutect2
- TRAF3IP1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.113); catalogued as COSV64853268; called by muse, mutect2
- TTBK1 | c.506A>G p.Y169C | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.051); catalogued as COSV52493225; called by muse, mutect2, varscan2
- TTC21A | c.3457A>G p.I1153V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs767863208, COSV56188895; called by muse, mutect2, varscan2
- TTN | c.80014G>C p.E26672Q (on ENST00000591111; = p.E19248Q on NM_003319.4) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | PolyPhen benign (0.382); catalogued as COSV60158111, COSV60332347; called by muse, mutect2, varscan2
- TTN | c.45016G>C p.E15006Q (on ENST00000591111; = p.E7582Q on NM_003319.4) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | PolyPhen possibly damaging (0.651); catalogued as COSV60158144; called by muse, mutect2, varscan2
- TTN | c.19155C>A p.F6385L (on ENST00000591111; = p.F5458L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | PolyPhen benign (0.001); catalogued as COSV60158179, COSV60232549; called by muse, mutect2, varscan2
- TTN | c.12217G>C p.E4073Q (on ENST00000591111; = p.E4027Q on NM_003319.4) | Missense Mutation (SNP) | VAF 28/91 reads (31%) | catalogued as COSV60158190; called by muse, mutect2, varscan2
- TTPA | c.770A>G p.Q257R | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV52647320; called by muse, mutect2, varscan2
- TYK2 | c.2618-1G>C p.X873_splice | Splice Site (SNP) | VAF 8/64 reads (13%) | catalogued as COSV53388772; called by muse, mutect2, varscan2
- USH2A | c.7397C>T p.S2466F | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as COSV56391771; called by muse, mutect2
- UTP4 | c.172C>G p.H58D | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV58733460; called by muse, mutect2
- VARS1 | c.1457C>G p.S486C | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65155373; called by muse, mutect2
- VIT | c.771C>G p.F257L | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV101007461, COSV64897465; called by muse, mutect2, varscan2
- VPS8 | c.2149G>A p.E717K (on ENST00000625842 / NM_001349294.1; = p.E715K on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/245 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.056); catalogued as COSV54989442; called by muse, mutect2
- WDHD1 | c.3296A>G p.K1099R | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV62214590; called by muse, mutect2
- WDR7 | c.2254G>C p.E752Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.154); catalogued as COSV54356687; called by muse, mutect2, varscan2
- ZCCHC14 | c.863C>T p.S288F (on ENST00000268616; = p.S425F on NM_015144.3) | Missense Mutation (SNP) | VAF 101/334 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV51887653; called by muse, mutect2, varscan2
- ZCWPW1 | c.1679C>T p.S560L | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); catalogued as rs765733577, COSV52201073; called by muse, mutect2, varscan2
- ZFHX4 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); catalogued as rs774743599, COSV51455559; called by muse, mutect2, varscan2
- ZNF136 | c.1205A>G p.H402R | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.276); catalogued as COSV59711152; called by muse, mutect2, varscan2
- ZNF254 | c.1528A>G p.I510V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.108); catalogued as COSV61643346; called by muse, mutect2, varscan2
- ZNF418 | c.1837C>A p.H613N | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV68675756, COSV68676071; called by muse, mutect2, varscan2
- ZNF496 | c.66G>C p.R22S | Missense Mutation (SNP) | VAF 15/228 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); catalogued as COSV54178987; called by muse, mutect2
- ZNF775 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61613423; called by muse, mutect2, varscan2
- ZWILCH | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV57181220; called by muse, mutect2
- ZYX | c.1351A>G p.I451V | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51972612; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2554A>G p.R852G | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FOXD4L6 | c.1028G>A p.R343K | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.026); called by mutect2, varscan2
- LMX1B | c.455dup p.D154Rfs*15 | Frame Shift Ins (INS) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.551C>G p.A184G | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- MR1 | c.2_4del p.MG1_?2 | Translation Start Site (DEL) | VAF 23/71 reads (32%) | called by mutect2, pindel, varscan2
- TRAV8-6 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ABCA4 | c.1566G>A p.L522= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as COSV64674780; called by muse, mutect2
- ABCC8 | c.1398C>A p.V466= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV56852861; called by muse, varscan2
- ADAM12 | c.909G>A p.A303= | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as rs377680010; called by muse, mutect2, varscan2
- AGMO | c.1119C>T p.I373= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs1244219416, COSV61115719; called by muse, mutect2
- ANKAR | c.1818G>A p.P606= | Silent (SNP) | VAF 43/133 reads (32%) | catalogued as rs145408486; called by muse, mutect2, varscan2
- ATP2C1 | c.951G>A p.T317= | Silent (SNP) | VAF 19/240 reads (8%) | catalogued as rs147959633; called by muse, mutect2
- ATP8A1 | c.1356T>C p.F452= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV52539255; called by muse, mutect2
- ATXN7L3 | c.834T>C p.S278= (on ENST00000389384 / NM_001382309.1; = p.S285= on NM_001382308.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV60229211; called by muse, mutect2, varscan2
- CACNA1C | c.1857C>G p.L619= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV59737698; called by muse, mutect2
- CD84 | c.447T>C p.C149= | Silent (SNP) | VAF 49/124 reads (40%) | catalogued as COSV60869050; called by muse, mutect2, varscan2
- CDCA8 | c.180G>T p.R60= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV59239343; called by muse, mutect2, varscan2
- CDH12 | c.540C>T p.L180= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as COSV66403509, COSV66418477; called by muse, mutect2
- CDH8 | c.987T>C p.D329= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as COSV54877738; called by muse, mutect2, varscan2
- CHD6 | c.3381G>A p.E1127= | Silent (SNP) | VAF 6/119 reads (5%) | catalogued as COSV58558917; called by muse, mutect2
- COLEC10 | c.477C>T p.F159= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV60520683, COSV60521819; called by muse, mutect2
- CWH43 | c.1122G>A p.L374= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV56938202, COSV56940394; called by muse, mutect2, varscan2
- CYBRD1 | c.375G>C p.L125= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as COSV58426998; called by muse, mutect2
- CYP2A13 | c.207C>T p.F69= | Silent (SNP) | VAF 8/157 reads (5%) | catalogued as COSV57838653; called by muse, mutect2
- DCN | c.447C>T p.P149= | Silent (SNP) | VAF 80/188 reads (43%) | catalogued as rs915287751, COSV50007789; called by muse, mutect2, varscan2
- DSEL | c.1272C>T p.N424= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs1451177229, COSV59492627; called by muse, mutect2, varscan2
- DYNC1H1 | c.10014C>T p.I3338= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as COSV64138589; called by muse, mutect2, varscan2
- EIF2AK1 | c.1329G>C p.L443= | Silent (SNP) | VAF 12/168 reads (7%) | catalogued as COSV52236033; called by muse, mutect2
- EIF4ENIF1 | c.105C>G p.L35= | Silent (SNP) | VAF 87/230 reads (38%) | catalogued as rs774535032, COSV57516731; called by muse, mutect2, varscan2
- EPPK1 | c.5013C>G p.L1671= | Silent (SNP) | VAF 11/199 reads (6%) | catalogued as COSV73261641; called by muse, mutect2
- EQTN | c.852G>A p.E284= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as COSV66219060; called by muse, mutect2, varscan2
- FAAH | c.972C>G p.P324= | Silent (SNP) | VAF 18/412 reads (4%) | catalogued as rs1170097778, COSV54544684; called by muse, mutect2
- FAM104A | c.204C>T p.S68= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV52147390; called by muse, mutect2, varscan2
- FAT2 | c.3039C>T p.L1013= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV55823079; called by muse, mutect2
- FES | c.114C>G p.V38= | Silent (SNP) | VAF 15/176 reads (9%) | catalogued as COSV51577744; called by muse, mutect2
- FLOT1 | c.1233C>G p.L411= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as COSV58357939; called by muse, mutect2
- FOXJ2 | c.1566C>T p.P522= | Silent (SNP) | VAF 62/156 reads (40%) | catalogued as COSV50820106; called by muse, mutect2, varscan2
- FRAS1 | c.7302G>T p.P2434= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV53623064; called by muse, mutect2, varscan2
- GAS6 | c.564C>G p.L188= | Silent (SNP) | VAF 18/151 reads (12%) | catalogued as COSV59849791; called by muse, mutect2, varscan2
- GRHL2 | c.423C>T p.I141= | Silent (SNP) | VAF 43/230 reads (19%) | catalogued as COSV52544723; called by muse, mutect2, varscan2
- HNF4A | c.177G>C p.L59= | Silent (SNP) | VAF 37/175 reads (21%) | catalogued as COSV100291096, COSV57384972, COSV57387506; called by muse, mutect2, varscan2
- IFNA8 | c.357G>T p.L119= | Silent (SNP) | VAF 14/161 reads (9%) | catalogued as COSV66504698; called by muse, mutect2
- IGLV10-54 | c.69G>A p.L23= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as COSV101135419; called by muse, mutect2, varscan2
- KALRN | c.6447C>T p.L2149= (on ENST00000360013 / NM_001024660.4; = p.L452= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as COSV52259252; called by muse, mutect2, varscan2
- KCNK17 | c.583C>T p.L195= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as COSV64685973; called by muse, mutect2, varscan2
- KIF1B | c.2754C>T p.S918= (on ENST00000377086 / NM_001365952.1; = p.S872= on NM_015074.3) | Silent (SNP) | VAF 32/176 reads (18%) | catalogued as rs774630480, COSV55810972; called by muse, mutect2, varscan2
- KRTAP27-1 | c.623G>A p.*208= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV67001346; called by muse, mutect2, varscan2
- L3MBTL3 | c.141A>G p.T47= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV62386955; called by muse, mutect2, varscan2
- LRFN4 | c.1341C>T p.L447= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as COSV58921316; called by muse, mutect2
- LRRC8C | c.1420C>T p.L474= | Silent (SNP) | VAF 8/107 reads (7%) | catalogued as COSV64999199; called by muse, mutect2
- LRRTM4 | c.159A>C p.A53= | Silent (SNP) | VAF 64/121 reads (53%) | catalogued as COSV69140781; called by muse, mutect2, varscan2
- MACF1 | c.6447G>A p.L2149= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs1340718093, COSV57129000; called by muse, mutect2, varscan2
- MCF2L2 | c.720C>G p.L240= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV61056517; called by muse, mutect2, varscan2
- MTBP | c.1653C>A p.T551= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV59963973; called by muse, mutect2, varscan2
- MTIF2 | c.36A>T p.L12= | Silent (SNP) | VAF 51/287 reads (18%) | catalogued as COSV55052290; called by muse, mutect2, varscan2
- NAGK | c.861G>A p.L287= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV54903970; called by muse, mutect2, varscan2
- NCKAP1L | c.654G>T p.G218= | Silent (SNP) | VAF 76/202 reads (38%) | catalogued as rs780910100, COSV53208682; called by muse, varscan2
- NEB | c.2535G>A p.K845= | Silent (SNP) | VAF 9/170 reads (5%) | catalogued as COSV51429900; called by muse, mutect2
- NFATC2 | c.1734C>T p.P578= | Silent (SNP) | VAF 75/284 reads (26%) | catalogued as COSV65357785; called by muse, mutect2, varscan2
- NLRC4 | c.2806C>T p.L936= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV50872112, COSV50873011; called by muse, mutect2, varscan2
- OR2M3 | c.204C>T p.L68= | Silent (SNP) | VAF 168/672 reads (25%) | catalogued as rs1312225932, COSV71759122, COSV71759255; called by muse, mutect2, varscan2
- OR9A2 | c.714C>T p.A238= | Silent (SNP) | VAF 27/127 reads (21%) | catalogued as COSV63306820; called by muse, mutect2, varscan2
- OSR2 | c.567C>A p.I189= | Silent (SNP) | VAF 175/367 reads (48%) | catalogued as COSV52557760; called by muse, mutect2, varscan2
- PAPPA2 | c.2004T>C p.S668= | Silent (SNP) | VAF 134/382 reads (35%) | catalogued as rs1165738477, COSV62780830; called by muse, mutect2, varscan2
- PCDH15 | c.4527T>A p.S1509= | Silent (SNP) | VAF 54/105 reads (51%) | catalogued as rs1564539744, COSV57339307; called by muse, mutect2, varscan2
- PCDHA10 | c.60C>A p.L20= | Silent (SNP) | VAF 9/118 reads (8%) | catalogued as COSV56518352, COSV56544337; called by muse, mutect2
- PDE11A | c.588G>A p.L196= | Silent (SNP) | VAF 32/129 reads (25%) | catalogued as COSV53699201; called by muse, mutect2, varscan2
- PFKM | c.771C>G p.L257= | Silent (SNP) | VAF 48/125 reads (38%) | catalogued as rs1437929094, COSV56658580; called by muse, mutect2, varscan2
- PFKP | c.1560C>T p.A520= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as rs762268431, COSV66899260; called by muse, mutect2, varscan2
- PLEKHG1 | c.687G>A p.R229= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as COSV62048598; called by muse, mutect2, varscan2
- PLS1 | c.996G>A p.L332= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV61834461, COSV61835788; called by muse, mutect2, varscan2
- PNLIPRP1 | c.1197C>G p.T399= | Silent (SNP) | VAF 93/184 reads (51%) | catalogued as COSV62612306; called by muse, mutect2, varscan2
- PRB2 | c.609A>C p.G203= | Silent (SNP) | VAF 123/513 reads (24%) | catalogued as COSV66983508; called by muse, varscan2
- PRMT1 | c.261C>T p.F87= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV67159841; called by muse, mutect2
- PTAFR | c.690G>A p.A230= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs568828881, COSV59536884, COSV59537308; called by muse, mutect2, varscan2
- RANBP2 | c.6189C>G p.L2063= | Silent (SNP) | VAF 161/547 reads (29%) | catalogued as COSV51703275; called by muse, mutect2, varscan2
- REG3A | c.321T>C p.H107= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as rs1335232843, COSV59410248; called by muse, mutect2, varscan2
- RYR2 | c.10821C>T p.P3607= | Silent (SNP) | VAF 70/144 reads (49%) | catalogued as rs780588693, COSV63694245; called by muse, mutect2, varscan2
- SEMA4F | c.912G>T p.R304= | Silent (SNP) | VAF 83/168 reads (49%) | catalogued as COSV60283945; called by muse, mutect2, varscan2
- SERP1 | c.54C>T p.I18= | Silent (SNP) | VAF 13/177 reads (7%) | catalogued as COSV53526240; called by muse, mutect2
- SERPINB10 | c.744C>T p.L248= | Silent (SNP) | VAF 15/256 reads (6%) | catalogued as COSV53073896; called by muse, mutect2
- SLC26A6 | c.1716C>T p.L572= | Silent (SNP) | VAF 11/146 reads (8%) | catalogued as rs1273020426, COSV56573093; called by muse, mutect2
- SLC39A12 | c.345T>A p.S115= | Silent (SNP) | VAF 50/161 reads (31%) | catalogued as COSV66199848; called by muse, mutect2, varscan2
- SNX32 | c.546G>C p.L182= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV57449922; called by muse, mutect2
- SPR | c.399C>T p.C133= | Silent (SNP) | VAF 48/135 reads (36%) | catalogued as COSV52298094; called by muse, mutect2, varscan2
- SULF2 | c.1077C>T p.I359= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as rs758978210, COSV63414726; called by muse, mutect2
- SYN2 | c.759C>T p.P253= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV55139472; called by muse, mutect2, varscan2
- SYNJ1 | c.2646A>G p.P882= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs1198781961, COSV59150983; called by muse, mutect2, varscan2
- TAAR6 | c.684G>A p.A228= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs758772772, COSV51583605; called by muse, mutect2, varscan2
- TARS2 | c.1980C>T p.A660= | Silent (SNP) | VAF 33/159 reads (21%) | catalogued as COSV60873762; called by muse, mutect2, varscan2
- TBC1D31 | c.2424A>T p.R808= | Silent (SNP) | VAF 30/203 reads (15%) | catalogued as COSV54867738; called by muse, mutect2, varscan2
- TESPA1 | c.1110G>A p.Q370= (on ENST00000316577 / NM_001098815.3; = p.Q232= on NM_014796.2 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV57259708; called by muse, mutect2
- TMX2 | c.489T>C p.F163= | Silent (SNP) | VAF 74/198 reads (37%) | catalogued as rs1163858154, COSV53555072; called by muse, mutect2, varscan2
- UCKL1 | c.1317G>A p.R439= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs1214253572, COSV62403195; called by muse, mutect2, varscan2
- ZBP1 | c.762C>T p.I254= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV59062698; called by muse, mutect2, varscan2
- ZKSCAN1 | c.1452G>T p.T484= | Silent (SNP) | VAF 32/134 reads (24%) | catalogued as rs184051052, COSV60874528, COSV60875207; called by muse, mutect2, varscan2
- ZNF507 | c.459G>C p.V153= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as rs889295991, COSV61330531, COSV61332025; called by muse, mutect2
- ZNF775 | c.1353C>T p.C451= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV61613837; called by muse, mutect2, varscan2
- AKAP9 | c.6579+22A>T | Intron (SNP) | VAF 29/149 reads (19%) | catalogued as COSV62350284; called by muse, mutect2, varscan2
- CYP11B1 | c.396-588C>A | Intron (SNP) | VAF 19/146 reads (13%) | catalogued as COSV99454777; called by muse, varscan2
- CYP11B1 | c.396-589C>A | Intron (SNP) | VAF 19/145 reads (13%) | catalogued as rs866911923, COSV99454780; called by muse, varscan2
- DCHS2 | n.4737G>A | RNA (SNP) | VAF 26/59 reads (44%) | catalogued as COSV61770392; called by muse, mutect2, varscan2
- PRKAA1 | c.596+532G>A | Intron (SNP) | VAF 22/142 reads (15%) | catalogued as COSV99713139; called by muse, mutect2, varscan2
